Somatic mutation profile of tumor specimen C3N-00850-02 (aliquot CPT0027810009) from CPTAC case C3N-00850, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.9 years (23,707 days).
Specimen C3N-00850-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 895a643c-3800-463f-b4bb-9ac188834ce8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00850-71 (Blood Derived Normal), aliquot CPT0027890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8baf3aaf-bc22-4886-9096-b84051e83035

The open-access MAF lists 587 somatic variants for this specimen: 405 protein-altering or splice-affecting, 114 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 114, Frame Shift Del 76, Intron 41, Nonsense Mutation 15, Frame Shift Ins 14, 3'UTR 13, Splice Region 9, 3'Flank 7, Splice Site 5, 5'UTR 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.145del p.A49Pfs*5 | Frame Shift Del (DEL) | VAF 129/488 reads (26%) | catalogued as rs863223415, CM060789, COSV66359608; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.1489dup p.R497Pfs*6 | Frame Shift Ins (INS) | VAF 42/434 reads (10%) | catalogued as rs63750855; ClinVar: pathogenic; called by mutect2, pindel
- TCTN2 | c.76dup p.D26Gfs*52 | Frame Shift Ins (INS) | VAF 93/337 reads (28%) | catalogued as rs863225222; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOD1 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374503575; called by muse, mutect2, varscan2
- ALK | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 17/467 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV66558761; called by muse, mutect2
- ALKBH1 | c.1087del p.R363Efs*18 | Frame Shift Del (DEL) | VAF 31/237 reads (13%) | catalogued as COSV99380450; called by mutect2, pindel, varscan2
- ANK3 | c.12391A>T p.I4131F (on ENST00000280772 / NM_001320874.2; = p.I652F on NM_001149.3) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV55088578; called by muse, mutect2, varscan2
- ANKRD33 | c.182G>A p.R61Q (on ENST00000340970 / NM_001304459.2; = p.R196Q on NM_182608.4) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs186421964; called by muse, mutect2, varscan2
- ARID1B | c.6421G>T p.G2141* | Nonsense Mutation (SNP) | VAF 24/166 reads (14%) | catalogued as rs1554238100; called by muse, mutect2, varscan2
- ASIC1 | c.1579A>G p.T527A | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs753550712, COSV57318992; called by muse, mutect2, varscan2
- ATF3 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 108/601 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748196594; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | catalogued as rs768611141; called by mutect2, pindel
- ATP2A1 | c.2062G>A p.V688M | Missense Mutation (SNP) | VAF 36/549 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1358056169; called by muse, mutect2
- ATP2A3 | c.1657G>T p.G553C | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59235273; called by muse, mutect2
- ATP6V0A1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1226165648, COSV52876106; called by muse, mutect2, varscan2
- ATP9A | c.545dup p.N182Kfs*50 | Frame Shift Ins (INS) | VAF 27/113 reads (24%) | catalogued as rs1568825024; called by mutect2, varscan2
- BBS2 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 100/403 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs930659537; called by muse, mutect2, varscan2
- BCL6B | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs200507334, COSV53427105; called by muse, mutect2, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as rs749168305; called by mutect2, varscan2
- BICRA | c.4114G>A p.E1372K | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1342321443; called by muse, mutect2
- BIN1 | c.893C>T p.S298L (on ENST00000316724 / NM_001320642.1; = p.S282L on NM_004305.4) | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs754707833, CM1512486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSPH1 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as rs546690190, COSV100353580; called by muse, mutect2, varscan2
- C11orf95 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs1301521859; called by muse, mutect2, varscan2
- CACNA1F | c.3741G>A p.K1247= | Splice Region (SNP) | VAF 9/238 reads (4%) | catalogued as rs141171526; called by muse, mutect2
- CACNB4 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as rs750116399, COSV52399386; called by muse, mutect2, varscan2
- CAPN15 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1365437285; called by muse, mutect2, varscan2
- CCM2 | c.617C>A p.A206E | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51846595; called by muse, mutect2
- CD1E | c.157A>G p.S53G | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100937073; called by muse, mutect2
- CD4 | c.1211del p.G404Afs*11 | Frame Shift Del (DEL) | VAF 36/274 reads (13%) | catalogued as rs782711669; called by mutect2, varscan2
- CDH12 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV66385895; called by muse, mutect2, varscan2
- CDK5RAP3 | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1328817897; called by muse, mutect2
- CEP135 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779689049, COSV57260114; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CERS6 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1462178134, COSV59834452; called by muse, mutect2, varscan2
- CHPF2 | c.1941del p.S648Pfs*13 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs746469175; called by mutect2, pindel, varscan2
- CLCN2 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.885); catalogued as rs369890010; called by muse, mutect2, varscan2
- CLCN6 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747812996, COSV100411993; called by muse, mutect2
- COL22A1 | c.2781del p.G928Vfs*74 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs757423989, COSV100278932, COSV57328404; called by mutect2, pindel, varscan2
- COL27A1 | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs141967205; called by muse, mutect2
- COLGALT1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 108/371 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1214999229; called by muse, mutect2, varscan2
- CRP | c.230A>C p.Q77P | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs961338073; called by muse, mutect2, varscan2
- CSF3R | c.853del p.L285Sfs*43 | Frame Shift Del (DEL) | VAF 16/188 reads (9%) | catalogued as COSV58969619; called by mutect2, pindel
- CYLC2 | c.807del p.G270Vfs*86 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as rs757958924, COSV66336288; called by mutect2, varscan2
- DAAM2 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51394460; called by muse, mutect2, varscan2
- DCP1B | c.855del p.I286Lfs*97 | Frame Shift Del (DEL) | VAF 43/157 reads (27%) | catalogued as rs762149254; called by mutect2, pindel, varscan2
- DIP2C | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs1484389270; called by muse, mutect2, varscan2
- DLL1 | c.577C>A p.R193S | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV64537423; called by muse, mutect2, varscan2
- DRD5 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100431596; called by muse, mutect2, varscan2
- DSPP | c.3889T>G p.S1297A | Missense Mutation (SNP) | VAF 70/491 reads (14%) | PolyPhen benign (0.351); catalogued as rs1263135531; called by muse, mutect2, varscan2
- EIF1AX | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV65451736; called by muse, mutect2, varscan2
- ENTPD7 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs200214468; called by muse, mutect2, varscan2
- F13A1 | c.564G>A p.W188* | Nonsense Mutation (SNP) | VAF 99/316 reads (31%) | catalogued as COSV53558116; called by muse, mutect2, varscan2
- FABP3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs756453898, COSV60001212; called by muse, mutect2, varscan2
- FAM131A | c.400G>A p.A134T (on ENST00000310585; = p.A165T on NM_144635.5) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV55604152; called by muse, mutect2, varscan2
- FAM149A | c.1547C>A p.S516Y (on ENST00000356371 / NM_001367768.2; = p.S225Y on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57026582; called by muse, mutect2
- FAM170A | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs765270260, COSV100088780, COSV58926336; called by muse, mutect2, varscan2
- FAM98C | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs376393197; called by muse, mutect2, varscan2
- FBRSL1 | c.876del p.A293Pfs*121 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as rs1461432773; called by mutect2, pindel, varscan2
- FFAR3 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 169/543 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs781407676, COSV59909502; called by muse, mutect2, varscan2
- FGF19 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs114327249; called by muse, varscan2
- FLG | c.6871G>A p.G2291S | Missense Mutation (SNP) | VAF 169/883 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs200457079; called by muse, mutect2, varscan2
- FLNB | c.6859G>A p.A2287T | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1374840098; called by muse, mutect2
- FRAS1 | c.5574dup p.A1859Cfs*3 | Frame Shift Ins (INS) | VAF 44/166 reads (27%) | catalogued as rs753831692; called by mutect2, varscan2
- G2E3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs748765355; called by muse, mutect2, varscan2
- GPR45 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761119993, COSV51526096; called by muse, mutect2, varscan2
- GPR68 | c.397del p.R133Gfs*3 | Frame Shift Del (DEL) | VAF 60/204 reads (29%) | catalogued as COSV99473615; called by mutect2, pindel, varscan2
- GPRIN1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs367621405; called by muse, mutect2, varscan2
- GUCY2D | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs746020263; called by muse, mutect2, varscan2
- GYG1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 41/367 reads (11%) | catalogued as rs777291159, COSV99936855; called by muse, mutect2, varscan2
- H1-6 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 97/328 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs1041990834; called by muse, mutect2, varscan2
- HCN2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 11/334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99242505; called by muse, mutect2
- HEBP2 | c.593del p.N198Mfs*26 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | catalogued as rs769528102, COSV100874953; called by mutect2, pindel
- HECW1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs770163676, COSV67842048; called by mutect2, varscan2
- HGS | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61269725; called by muse, mutect2, varscan2
- HMCN1 | c.16539A>G p.S5513= | Splice Region (SNP) | VAF 30/532 reads (6%) | catalogued as rs61831359; called by muse, mutect2
- HMGCR | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780343008; called by muse, mutect2, varscan2
- HPS3 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867504860, COSV56052900; called by muse, mutect2, varscan2
- IGHV1-46 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 59/513 reads (12%) | catalogued as rs548625495; called by mutect2, varscan2
- INO80D | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs922472546; called by muse, mutect2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IRX5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1455353740; called by muse, mutect2, varscan2
- ITFG1 | c.451A>G p.N151D | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs771542280; called by muse, varscan2
- ITGB4 | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs762521380; called by muse, mutect2, varscan2
- KCTD13 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 130/457 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs373591971; called by muse, mutect2, varscan2
- KIAA0319 | c.3119T>C p.I1040T | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV65497543; called by muse, mutect2, varscan2
- LACTBL1 | c.359G>A p.G120D (on ENST00000618559; = p.G149D on NM_001289974.2) | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs1311006587; called by muse, mutect2
- LAMC2 | c.2161A>G p.R721G | Missense Mutation (SNP) | VAF 47/709 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs778547833; called by muse, mutect2
- LIN37 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs913798209; called by muse, mutect2, varscan2
- LYST | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 112/852 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1037862310, COSV101090441; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 111/399 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.317); catalogued as COSV51726429; called by muse, mutect2, varscan2
- MEGF8 | c.6820C>T p.R2274C (on ENST00000251268 / NM_001271938.2; = p.R2207C on NM_001410.3) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs770418164, COSV52077521; called by mutect2, varscan2
- MRGPRX4 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as rs767806276, COSV58589771; called by muse, mutect2
- MROH2A | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs531831808; called by muse, mutect2, varscan2
- MYO5B | c.2851A>G p.T951A | Missense Mutation (SNP) | VAF 112/403 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53221171; called by muse, mutect2, varscan2
- NEUROG1 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs760775346; called by muse, mutect2, varscan2
- NF1 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1060500288, COSV62205174, COSV62212110, COSV62222819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN2 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); catalogued as rs760849360, COSV57211544; called by muse, mutect2, varscan2
- NONO | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 21/78 reads (27%) | catalogued as COSV104370442; called by muse, varscan2
- NOP14 | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs1402201015; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- OBSCN | c.9614G>A p.R3205H | Missense Mutation (SNP) | VAF 78/552 reads (14%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.732); catalogued as rs765476344, COSV52778720; called by muse, mutect2, varscan2
- P2RY8 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs751492615, COSV101184211; called by muse, mutect2, varscan2
- PCDHA13 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 102/373 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.097); catalogued as rs143828814, COSV56481595; called by muse, mutect2, varscan2
- PCDHA2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV65364468; called by muse, mutect2
- PCDHB5 | c.2198G>T p.G733V | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV99167718; called by muse, mutect2, varscan2
- PCDHGA3 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.185); catalogued as rs745349592, COSV53916955, COSV54017901; called by muse, mutect2, varscan2
- PCLO | c.3077del p.K1026Sfs*11 | Frame Shift Del (DEL) | VAF 71/232 reads (31%) | catalogued as COSV61631380; called by mutect2, pindel, varscan2
- PEG3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs762679674, COSV55624040; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PHF2 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1271286430; called by muse, mutect2, varscan2
- PHRF1 | c.2509G>A p.G837S (on ENST00000264555 / NM_001286581.2; = p.G836S on NM_020901.4) | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199793786; called by muse, mutect2, varscan2
- PIK3R1 | c.1982_1983dup p.V662* (on ENST00000521381 / NM_181523.3; = p.V392* on NM_181504.4) | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | catalogued as COSV57126568; called by mutect2, pindel, varscan2
- PITPNM3 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs780611896; called by muse, mutect2
- PLCB3 | c.3295G>T p.D1099Y | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749911369; called by muse, mutect2, varscan2
- PNPLA7 | c.3244G>T p.G1082W | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53000688; called by muse, mutect2, varscan2
- POMT2 | c.1577-8del | Splice Region (DEL) | VAF 88/412 reads (21%) | catalogued as rs749856419; ClinVar: likely benign; called by mutect2, pindel, varscan2
- PPP2R1A | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59048712; called by muse, mutect2, varscan2
- PTBP1 | c.1525A>G p.I509V (on ENST00000349038 / NM_031991.4; = p.I535V on NM_002819.5) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs767958955; called by muse, mutect2, varscan2
- RBPJL | c.1190del p.G397Afs*61 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | catalogued as rs1360152862; called by mutect2, pindel, varscan2
- RPA2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs1476016273; called by muse, mutect2, varscan2
- RTL5 | c.1643del p.P548Lfs*52 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as COSV101030286; called by mutect2, pindel, varscan2
- SAMSN1 | c.795G>A p.W265* (on ENST00000647101; = p.W37* on NM_001256370.1) | Nonsense Mutation (SNP) | VAF 46/140 reads (33%) | catalogued as rs1328552974; called by muse, mutect2, varscan2
- SAP130 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs867289279; called by muse, mutect2, varscan2
- SCN2A | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs745774658, COSV51846021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2D4B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs747664374, COSV57897251; called by muse, mutect2, varscan2
- SLC12A3 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99343945; called by muse, mutect2, varscan2
- SLC13A2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 156/493 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs542443147, COSV58992578; called by muse, mutect2, varscan2
- SLC30A8 | c.374C>A p.S125* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV69969239; called by muse, mutect2, varscan2
- SON | c.5194G>A p.D1732N | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as rs200054412, COSV51650925; called by muse, mutect2
- SPEG | c.4940G>A p.R1647Q | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.555); catalogued as rs779131208; called by muse, mutect2, varscan2
- SRGAP3 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 27/427 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100840960; called by muse, mutect2
- STK11IP | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs368637601; called by muse, mutect2, varscan2
- STON2 | c.2278G>A p.V760M (on ENST00000649389 / NM_001366849.2; = p.V703M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as rs1266038011, COSV50846172; called by muse, mutect2, varscan2
- SUPT16H | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV53527973; called by muse, mutect2, varscan2
- SZT2 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 78/512 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as rs749086217; called by muse, mutect2, varscan2
- SZT2 | c.7274del p.P2425Lfs*9 (on ENST00000634258 / NM_001365999.1; = p.P2368Lfs*9 on NM_015284.4) | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | catalogued as COSV65175105; called by mutect2, pindel, varscan2
- SZT2 | c.9875G>A p.R3292Q (on ENST00000634258 / NM_001365999.1; = p.R3235Q on NM_015284.4) | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs761190000; called by muse, mutect2, varscan2
- TACC2 | c.5135G>A p.S1712N | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs200641398; called by muse, mutect2, varscan2
- TAF4 | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs772049393, COSV53341750, COSV53343171; called by muse, mutect2, varscan2
- TCL1B | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100525740, COSV61552010; called by muse, mutect2, varscan2
- TLNRD1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51259420; called by muse, mutect2, varscan2
- TLR9 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200533822; called by muse, mutect2, varscan2
- TOPAZ1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs1371718823, COSV59075212; called by muse, mutect2, varscan2
- TRMT10B | c.297C>T p.G99= | Splice Region (SNP) | VAF 26/144 reads (18%) | catalogued as rs1312035487; called by muse, mutect2
- TTC6 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV73287863; called by muse, mutect2
- TUBB6 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100480988; called by muse, mutect2, varscan2
- TULP4 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 112/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748974236; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 46/139 reads (33%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- URB2 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs768638606; called by muse, mutect2, varscan2
- USP13 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 33/162 reads (20%) | catalogued as rs759284752; called by muse, mutect2, varscan2
- USP32 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1182476634; called by muse, mutect2
- UTF1 | c.164del p.P55Rfs*221 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as rs1451188173; called by mutect2, pindel, varscan2
- VPS52 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1283456787, COSV69385199; called by muse, mutect2, varscan2
- WDR64 | c.3191del p.N1064Ifs*2 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | catalogued as rs1402216161; called by mutect2, varscan2
- WDR89 | c.1079_1082del p.K360Rfs*3 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs1566787367; called by pindel, varscan2
- WNT5B | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs763794129; called by muse, mutect2
- WRAP53 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 109/399 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs768089496, COSV99873054; called by muse, mutect2, varscan2
- WWC3 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as rs986866560, COSV101082009; called by muse, mutect2, varscan2
- XIRP2 | c.7964G>A p.R2655Q (on ENST00000628543; = p.R2830Q on NM_152381.6) | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368268974; called by muse, mutect2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | catalogued as rs761507279; called by mutect2, varscan2
- ZHX2 | c.1760T>C p.M587T | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1286029833; called by muse, mutect2, varscan2
- ZNF185 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369058817; called by muse, mutect2, varscan2
- ZNF2 | c.287del p.N96Tfs*29 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as COSV54638492; called by mutect2, pindel, varscan2
- ZNF469 | c.3872C>T p.P1291L (on ENST00000437464; = p.P1319L on NM_001367624.2) | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs770376107; called by muse, mutect2, varscan2
- ZNF485 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs368421127; called by muse, mutect2, varscan2
- ZNF71 | c.71del p.G24Dfs*45 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as COSV60146904; called by mutect2, pindel, varscan2
- ZNF862 | c.811dup p.D271Gfs*22 | Frame Shift Ins (INS) | VAF 34/124 reads (27%) | catalogued as rs769847259; called by mutect2, varscan2
- ZXDA | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV62387743; called by muse, mutect2
- ABCF3 | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- ACHE | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- ACOT9 | c.1274T>C p.M425T | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTG2 | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- ADAMTS5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ADAMTSL1 | c.4223T>C p.L1408P | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ALDH1L2 | c.2736A>C p.E912D | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- AMBRA1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANHX | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKAR | c.2182T>C p.C728R | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKS1A | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- APBB1IP | c.1412A>G p.Q471R | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- APC2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- APLP2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- APOB | c.2438T>A p.I813N | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ARHGAP32 | c.3845T>C p.V1282A (on ENST00000310343 / NM_001378025.1; = p.V933A on NM_014715.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP4 | c.2090C>A p.P697H | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ARHGEF11 | c.1633del p.S545Afs*21 | Frame Shift Del (DEL) | VAF 48/330 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 38/141 reads (27%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 18/206 reads (9%) | called by mutect2, pindel
- ARID1A | c.6377G>A p.S2126N | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2
- ASH1L | c.2908del p.I970Lfs*9 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- ATP6V1B2 | c.782del p.L261* | Frame Shift Del (DEL) | VAF 25/221 reads (11%) | called by mutect2, pindel, varscan2
- BCAS3 | c.1666del p.S556Pfs*2 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- BCL11B | c.1453G>A p.A485T (on ENST00000357195 / NM_001282237.2; = p.A414T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- BOD1L1 | c.5762C>T p.A1921V | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BRWD3 | c.2252C>T p.T751I | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CALR | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 27/351 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPRIN2 | c.1297T>C p.S433P | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.387); called by muse, mutect2
- CATSPERE | c.1136del p.N379Tfs*3 | Frame Shift Del (DEL) | VAF 41/315 reads (13%) | called by mutect2, pindel, varscan2
- CBX2 | c.1088A>C p.N363T | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCDC168 | c.12706del p.M4236Wfs*14 | Frame Shift Del (DEL) | VAF 76/313 reads (24%) | called by mutect2, pindel, varscan2
- CCDC33 | c.2138C>A p.P713H | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2
- CCDC66 | c.198del p.K66Nfs*22 (on ENST00000394672 / NM_001353147.1; = p.K32Nfs*22 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | called by pindel, varscan2
- CD68 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CDH4 | c.2380-2A>G p.X794_splice | Splice Site (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- CEP43 | c.191del p.K64Sfs*3 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- CHCHD3 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2
- CHD6 | c.7447A>G p.N2483D | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CHKB | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 101/365 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST7 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CIC | c.404del p.P135Qfs*70 | Frame Shift Del (DEL) | VAF 30/257 reads (12%) | called by mutect2, pindel, varscan2
- CMYA5 | c.10751del p.N3584Mfs*5 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | called by pindel, varscan2
- COL13A1 | c.1768del p.X590_splice (on ENST00000398978 / NM_001130103.2; = p.X518_splice on NM_080798.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 36/121 reads (30%) | called by mutect2, pindel, varscan2
- COL21A1 | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL5A2 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- COL9A3 | c.281del p.P94Lfs*35 | Frame Shift Del (DEL) | VAF 82/365 reads (22%) | called by mutect2, pindel, varscan2
- CORO2B | c.208del p.L70Wfs*53 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- CRNKL1 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CSPG5 | c.1306C>T p.L436F | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- CWC22 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF8 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- DCHS1 | c.8863G>A p.A2955T | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DDX46 | c.816del p.A273Qfs*12 | Frame Shift Del (DEL) | VAF 46/168 reads (27%) | called by mutect2, pindel, varscan2
- DHODH | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DHX15 | c.2299G>C p.D767H | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- DMPK | c.1584G>T p.Q528H | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRTC2 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- DNER | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK3 | c.5972T>G p.V1991G | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); called by muse, mutect2
- ECEL1 | c.1949T>G p.I650S | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EIF4B | c.1208G>T p.R403I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by mutect2, varscan2
- ENOSF1 | c.703T>A p.Y235N (on ENST00000340116 / NM_001354066.2; = p.Y187N on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENSA | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); called by muse, mutect2
- ENTPD7 | c.388del p.I130Sfs*23 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- EPHA3 | c.402A>T p.K134N | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ERICH2 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- ESF1 | c.295del p.T99Pfs*12 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- FAM193A | c.3721_3723del p.A1241del (on ENST00000324666 / NM_001256666.1; = p.A1200del on NM_003704.3) | In Frame Del (DEL) | VAF 58/197 reads (29%) | called by mutect2, pindel, varscan2
- FAM200B | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FAM222B | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FAM83H | c.1094del p.G365Afs*180 | Frame Shift Del (DEL) | VAF 83/254 reads (33%) | called by mutect2, pindel, varscan2
- FASTKD3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBLN2 | c.478T>C p.C160R | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGF22 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FIZ1 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- FKBP9 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLRT3 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- FOXN2 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GBP3 | c.983del p.K328Rfs*40 | Frame Shift Del (DEL) | VAF 81/732 reads (11%) | called by mutect2, pindel
- GJB4 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPR150 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GREB1 | c.3892del p.L1298Cfs*6 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- GTF2I | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GTF3C3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCN4 | c.2620C>A p.L874I | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HGD | c.282+3A>G | Splice Region (SNP) | VAF 25/323 reads (8%) | called by muse, mutect2
- HHAT | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- HOXC5 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HS3ST1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HSPG2 | c.11672-3del | Splice Region (DEL) | VAF 75/253 reads (30%) | called by mutect2, pindel, varscan2
- HTR3E | c.1271G>T p.W424L (on ENST00000415389 / NM_001256613.1; = p.W439L on NM_182589.2) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IARS2 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IFIT1B | c.826dup p.M276Nfs*36 | Frame Shift Ins (INS) | VAF 40/159 reads (25%) | called by mutect2, pindel, varscan2
- IFITM2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFRD2 | c.851del p.G284Afs*55 | Frame Shift Del (DEL) | VAF 33/157 reads (21%) | called by mutect2, pindel, varscan2
- IGF2BP3 | c.995A>T p.N332I | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel
- IQSEC2 | c.3166A>C p.K1056Q (on ENST00000642864 / NM_001111125.3; = p.K851Q on NM_015075.2) | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- JPH3 | c.1740del p.V581Cfs*28 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, varscan2
- KCNA7 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KIF3B | c.1494A>C p.E498D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- KLRG2 | c.648dup p.T217Hfs*157 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- KRT26 | c.533dup p.N178Kfs*2 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- KRTAP10-5 | c.501del p.C168Afs*201 | Frame Shift Del (DEL) | VAF 64/479 reads (13%) | called by mutect2, pindel, varscan2
- LARP4B | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2
- LCTL | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- LRRC3 | c.439del p.L147Cfs*14 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
- LRRK2 | c.6791T>G p.L2264W | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LY6K | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LYPD6 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MAGEH1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MAP3K21 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- MAP3K8 | c.1332_1333del p.Y445Hfs*20 | Frame Shift Del (DEL) | VAF 44/172 reads (26%) | called by pindel, varscan2
- MAP7 | c.1232_1233del p.T411Sfs*2 | Frame Shift Del (DEL) | VAF 36/152 reads (24%) | called by pindel, varscan2
- MBD3L2 | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 125/1038 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MBD5 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 74/437 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MDGA1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MED13 | c.5203T>G p.L1735V | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- MED13 | c.4167del p.F1389Lfs*13 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- MEP1B | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 134/467 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MS4A14 | c.475T>G p.F159V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A18 | c.624G>T p.K208N (on ENST00000398983; = p.K210N on NM_001354471.1) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC2 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC5AC | c.14623T>C p.C4875R | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH3 | c.3363G>T p.E1121D | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- MYH4 | c.4489G>A p.D1497N | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYO5B | c.2939G>T p.R980M | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- N4BP2 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- NBEA | c.6747del p.V2250Lfs*10 | Frame Shift Del (DEL) | VAF 20/168 reads (12%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDUFAF2 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 66/643 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEFM | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 38/596 reads (6%) | called by muse, mutect2
- NEU4 | c.1085T>A p.L362Q (on ENST00000391969 / NM_001167602.3; = p.L374Q on NM_080741.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NEURL4 | c.-4_4delinsT | Translation Start Site (DEL) | VAF 9/25 reads (36%) | called by pindel, varscan2*
- NFIC | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NFIX | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- NLGN4X | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 78/587 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- NPAS3 | c.2297dup p.G767Rfs*86 (on ENST00000356141 / NM_001164749.2; = p.G735Rfs*86 on NM_022123.3) | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- NR2E3 | c.480dup p.T161Hfs*21 | Frame Shift Ins (INS) | VAF 70/270 reads (26%) | called by mutect2, pindel, varscan2
- NRBP1 | c.591del p.I198Sfs*6 | Frame Shift Del (DEL) | VAF 39/139 reads (28%) | called by mutect2, pindel, varscan2
- NRROS | c.340del p.D114Tfs*31 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | called by mutect2, pindel, varscan2
- NUGGC | c.2221del p.D741Mfs*24 | Frame Shift Del (DEL) | VAF 88/257 reads (34%) | called by mutect2, pindel, varscan2
- NUP188 | c.4642C>T p.H1548Y | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- NUP210L | c.5574del p.F1858Lfs*11 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel
- ONECUT2 | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); called by muse, mutect2
- PCDHGA11 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PHKA1 | c.3460del p.I1154* | Frame Shift Del (DEL) | VAF 69/247 reads (28%) | called by mutect2, pindel, varscan2
- PIAS3 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2
- PIWIL3 | c.116dup p.Q40Sfs*17 | Frame Shift Ins (INS) | VAF 15/130 reads (12%) | called by mutect2, pindel, varscan2
- PKD1 | c.5018G>C p.G1673A | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PLA2G3 | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- PLXNB2 | c.2479A>T p.N827Y | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEC | c.1089dup p.Q364Tfs*8 | Frame Shift Ins (INS) | VAF 41/149 reads (28%) | called by mutect2, pindel, varscan2
- POU2F1 | c.2102G>T p.G701V (on ENST00000541643 / NM_001365848.1; = p.G724V on NM_002697.4) | Missense Mutation (SNP) | VAF 120/652 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP4R3A | c.1918T>G p.L640V (on ENST00000554943 / NM_001366432.1; = p.L627V on NM_001284280.1) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PRICKLE2 | c.742A>T p.K248* (on ENST00000295902; = p.K192* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- PTPRT | c.1106del p.G369Vfs*28 | Frame Shift Del (DEL) | VAF 62/201 reads (31%) | called by mutect2, pindel, varscan2
- PUM2 | c.1054dup p.V352Gfs*17 | Frame Shift Ins (INS) | VAF 14/164 reads (9%) | called by mutect2, pindel
- PXDNL | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- RC3H1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- REST | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REXO4 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS9 | c.1509del p.R504Gfs*83 | Frame Shift Del (DEL) | VAF 40/155 reads (26%) | called by mutect2, pindel, varscan2
- RGS9 | c.2010del p.W671Gfs*21 | Frame Shift Del (DEL) | VAF 26/290 reads (9%) | called by mutect2, pindel
- RPGR | c.2539A>G p.T847A (on ENST00000339363 / NM_001367249.1; = p.T642A on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPGRIP1 | c.3427T>C p.Y1143H | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RRBP1 | c.10T>A p.Y4N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL5 | c.1515A>C p.R505S | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SATL1 | c.806T>C p.M269T (on ENST00000395409; = p.M456T on NM_001012980.2) | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCRT2 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6C | c.2582del p.P861Lfs*37 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel
- SHOC2 | c.304T>G p.S102A | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC11A2 | c.720del p.F240Lfs*19 (on ENST00000394904 / NM_001379455.1; = p.F211Lfs*19 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/341 reads (12%) | called by mutect2, varscan2
- SLC25A23 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- SLC2A12 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35E4 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SLC47A1 | c.135+3_135+6del p.X45_splice | Splice Site (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SMG7 | c.1070A>T p.N357I | Missense Mutation (SNP) | VAF 56/358 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, varscan2
- SMOC2 | c.1166T>C p.V389A (on ENST00000356284 / NM_001166412.2; = p.V400A on NM_022138.3) | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SNRPA1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SOX15 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SOX2 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX8 | c.1081T>C p.C361R | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SPP1 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2
- STRADB | c.546C>T p.H182= | Splice Region (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- SULT2A1 | c.99G>T p.R33S | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- SYMPK | c.2840T>A p.I947N | Missense Mutation (SNP) | VAF 61/421 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SZT2 | c.2621del p.P874Hfs*57 | Frame Shift Del (DEL) | VAF 57/222 reads (26%) | called by mutect2, pindel, varscan2
- TACC2 | c.4625_4628del p.E1542Afs*14 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- TAS2R31 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.127); called by muse, varscan2
- TBC1D23 | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TBC1D5 | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBL1X | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- TCHH | c.5013A>C p.E1671D | Missense Mutation (SNP) | VAF 66/776 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- TEAD1 | c.716T>A p.F239Y | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TFRC | c.1535del p.N512Mfs*2 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- THBS3 | c.2111A>T p.D704V | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGD3 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR9 | c.2716C>A p.L906M | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM144 | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TOPBP1 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC28 | c.6595G>A p.A2199T | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.16454G>A p.C5485Y (on ENST00000591111; = p.C4558Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/186 reads (8%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.8878G>A p.V2960I (on ENST00000591111; = p.V2914I on NM_003319.4) | Missense Mutation (SNP) | VAF 73/205 reads (36%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TUBA4B | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TUBB4B | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UBE3B | c.379A>C p.T127P | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- UBN2 | c.109del p.R37Gfs*149 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- UBTF | c.475-3del | Splice Region (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- UCHL5 | c.246+2T>G p.X82_splice | Splice Site (SNP) | VAF 33/162 reads (20%) | called by muse, mutect2, varscan2
- ULK3 | c.1245A>G p.A415= | Splice Region (SNP) | VAF 36/129 reads (28%) | called by muse, mutect2, varscan2
- UNC13A | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- UPK3B | c.308C>T p.A103V (on ENST00000257632; = p.A48V on NM_001347684.2) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- USP33 | c.359_361del p.E120del | In Frame Del (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2
- USP4 | c.2615A>T p.N872I | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS41 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- VWA3B | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, varscan2
- WFIKKN1 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPR1 | c.1039T>C p.Y347H | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- ZFHX4 | c.6170del p.P2057Hfs*26 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | called by mutect2, varscan2
- ZNF256 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZNF277 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.2); called by muse, mutect2
- ZNF432 | c.1122_1123del p.I374Mfs*3 | Frame Shift Del (DEL) | VAF 44/166 reads (27%) | called by pindel, varscan2
- ZNF440 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF578 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, varscan2
- ZNF704 | c.52del p.M18Cfs*15 | Frame Shift Del (DEL) | VAF 58/206 reads (28%) | called by mutect2, varscan2
- ZNF728 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ZNF91 | c.1751A>T p.N584I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZSCAN9 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC138647.1 | c.168C>T p.R56= | Silent (SNP) | VAF 81/217 reads (37%) | catalogued as rs1563789004; called by muse, mutect2, varscan2
- ACLY | c.1296C>A p.A432= | Silent (SNP) | VAF 14/167 reads (8%) | catalogued as COSV100709750; called by muse, mutect2
- ADAMTS10 | c.2946G>A p.P982= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1015178245; called by muse, mutect2
- ADCY6 | c.2229C>A p.T743= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- AFAP1L2 | c.1315C>T p.L439= | Silent (SNP) | VAF 58/234 reads (25%) | called by muse, mutect2, varscan2
- ALKBH2 | c.105A>G p.E35= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- AP1M1 | c.729G>A p.R243= | Silent (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2
- ARFGEF1 | c.4578C>T p.C1526= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV51602547; called by muse, mutect2, varscan2
- ARPC2 | c.519C>T p.D173= | Silent (SNP) | VAF 51/204 reads (25%) | called by muse, mutect2, varscan2
- ATP1A2 | c.2346C>T p.P782= | Silent (SNP) | VAF 79/335 reads (24%) | catalogued as rs754391034, COSV63402172, COSV63406087; called by muse, mutect2, varscan2
- B4GALNT4 | c.1515G>A p.P505= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs767558658; called by muse, mutect2, varscan2
- C1orf167 | c.1671G>T p.L557= | Silent (SNP) | VAF 53/174 reads (30%) | called by muse, mutect2, varscan2
- CCDC9B | c.1230C>T p.C410= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1416445407; called by muse, mutect2, varscan2
- CDC42BPA | c.4185C>A p.L1395= (on ENST00000334218 / NM_001366019.2; = p.L1382= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- CDH19 | c.1170C>T p.G390= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as rs771241982, COSV100051616, COSV100052473; called by muse, mutect2, varscan2
- CDKN2A | c.306G>A p.A102= | Silent (SNP) | VAF 62/488 reads (13%) | catalogued as COSV58724994, COSV58728253; called by muse, varscan2
- CFDP1 | c.129G>A p.E43= | Silent (SNP) | VAF 35/134 reads (26%) | called by muse, mutect2, varscan2
- DIO3 | c.261C>T p.N87= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as rs1225616354; called by muse, mutect2, varscan2
- DNAH10 | c.5515C>A p.R1839= (on ENST00000409039; = p.R1778= on NM_207437.3) | Silent (SNP) | VAF 52/158 reads (33%) | catalogued as COSV68996299; called by muse, mutect2, varscan2
- DNAH7 | c.10762T>C p.L3588= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- DND1 | c.852C>T p.G284= | Silent (SNP) | VAF 63/584 reads (11%) | called by muse, mutect2, varscan2
- DOCK6 | c.1053C>T p.I351= | Silent (SNP) | VAF 59/226 reads (26%) | called by muse, mutect2, varscan2
- DPPA4 | c.210T>C p.T70= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- ECI1 | c.306T>G p.G102= | Silent (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- ERCC2 | c.1875C>T p.Y625= | Silent (SNP) | VAF 60/407 reads (15%) | catalogued as rs146538967; called by muse, mutect2, varscan2
- F13B | c.1725A>G p.P575= | Silent (SNP) | VAF 40/227 reads (18%) | called by muse, mutect2, varscan2
- F9 | c.315C>T p.G105= | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as rs757434127, COSV54382454, COSV54382530; called by muse, mutect2, varscan2
- FAM120B | c.216A>G p.R72= | Silent (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- FAM171A2 | c.2349C>T p.S783= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV50006412; called by muse, mutect2, varscan2
- FAM237A | c.117G>A p.L39= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV101405583, COSV69304927; called by muse, mutect2, varscan2
- FARS2 | c.867T>G p.L289= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- FASLG | c.171G>A p.P57= | Silent (SNP) | VAF 50/634 reads (8%) | catalogued as rs1224639372; called by muse, mutect2
- FBXL5 | c.1878T>A p.P626= | Silent (SNP) | VAF 67/249 reads (27%) | called by muse, mutect2, varscan2
- FRMD7 | c.1066C>T p.L356= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- GRIN2A | c.3303C>T p.V1101= | Silent (SNP) | VAF 66/244 reads (27%) | catalogued as rs774772499, COSV58043182; called by muse, mutect2, varscan2
- HECTD3 | c.1605A>G p.E535= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- HMGCL | c.30G>A p.R10= | Silent (SNP) | VAF 45/363 reads (12%) | catalogued as rs1284448239; called by muse, mutect2, varscan2
- HOMER3 | c.441C>T p.N147= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55355581; called by muse, mutect2, varscan2
- HP1BP3 | c.90A>G p.L30= | Silent (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- IQSEC1 | c.2529C>T p.N843= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs764683803; called by muse, mutect2
- ITGB2 | c.2262C>T p.S754= (on ENST00000302347; = p.S730= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 150/486 reads (31%) | catalogued as rs375930896; called by mutect2, varscan2
- ITPR1 | c.783C>T p.H261= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as rs542591284; called by muse, mutect2, varscan2
- ITPR3 | c.4032C>T p.H1344= | Silent (SNP) | VAF 62/208 reads (30%) | called by muse, mutect2, varscan2
- JMJD4 | c.417A>G p.P139= | Silent (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- KCNG4 | c.1113C>T p.F371= | Silent (SNP) | VAF 132/455 reads (29%) | catalogued as rs774390689; called by muse, mutect2, varscan2
- KCNH4 | c.1587C>T p.N529= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as rs765016708, COSV99237337; called by muse, mutect2
- KIAA1109 | c.14949T>A p.L4983= | Silent (SNP) | VAF 93/308 reads (30%) | called by muse, mutect2, varscan2
- KIF16B | c.852C>T p.N284= | Silent (SNP) | VAF 24/192 reads (13%) | catalogued as rs541939415, COSV61706823; called by muse, mutect2, varscan2
- KL | c.483C>T p.S161= | Silent (SNP) | VAF 66/211 reads (31%) | called by muse, mutect2, varscan2
- KLHL23 | c.1503C>T p.C501= | Silent (SNP) | VAF 73/208 reads (35%) | catalogued as rs781533649, COSV99776125; called by muse, mutect2, varscan2
- LCE3C | c.201C>A p.R67= | Silent (SNP) | VAF 65/395 reads (16%) | called by muse, mutect2, varscan2
- LCMT2 | c.141C>G p.R47= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV59790936; called by muse, mutect2, varscan2
- LOXHD1 | c.1050G>A p.E350= | Silent (SNP) | VAF 26/186 reads (14%) | called by muse, varscan2
- LRIG1 | c.2874G>A p.Q958= | Silent (SNP) | VAF 76/374 reads (20%) | catalogued as COSV56244352; called by muse, mutect2, varscan2
- MDN1 | c.6279C>T p.N2093= | Silent (SNP) | VAF 33/201 reads (16%) | catalogued as COSV65525093; called by muse, mutect2, varscan2
- MEF2B | c.942C>T p.C314= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV50773755; called by muse, mutect2
- MLXIPL | c.564C>T p.Y188= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs781928279; called by muse, mutect2, varscan2
- MTTP | c.1515C>A p.T505= | Silent (SNP) | VAF 44/285 reads (15%) | called by muse, mutect2, varscan2
- MUC5B | c.1590A>G p.T530= | Silent (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- MUC5B | c.16314C>T p.D5438= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as rs370834666; called by muse, mutect2, varscan2
- MYO5C | c.1434A>G p.E478= | Silent (SNP) | VAF 46/150 reads (31%) | called by muse, varscan2
- NKX1-1 | c.294T>C p.R98= | Silent (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- NKX2-5 | c.288C>A p.A96= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- NOTCH1 | c.687C>T p.N229= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs535217359; ClinVar: likely benign; called by muse, mutect2, varscan2
- NR1I2 | c.1107C>T p.F369= | Silent (SNP) | VAF 46/288 reads (16%) | catalogued as rs369188703; called by muse, mutect2, varscan2
- OR10H1 | c.117G>A p.L39= | Silent (SNP) | VAF 23/219 reads (11%) | called by muse, mutect2, varscan2
- OR8D1 | c.657C>A p.A219= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs369956026; called by muse, mutect2, varscan2
- OTC | c.1024C>T p.L342= | Silent (SNP) | VAF 23/365 reads (6%) | catalogued as COSV50003798; called by muse, mutect2
- OTOF | c.3363C>T p.P1121= (on ENST00000272371 / NM_194248.3; = p.P374= on NM_004802.4) | Silent (SNP) | VAF 77/321 reads (24%) | catalogued as rs745957247, COSV55503703; ClinVar: likely benign; called by muse, mutect2, varscan2
- OTUD7A | c.1497C>T p.N499= (on ENST00000307050 / NM_001382637.1; = p.N492= on NM_130901.3) | Silent (SNP) | VAF 34/483 reads (7%) | catalogued as rs377421686; called by muse, mutect2
- PCDH8 | c.501C>T p.N167= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs1278922872; called by muse, mutect2
- PCDHB4 | c.1605C>T p.R535= | Silent (SNP) | VAF 80/846 reads (9%) | catalogued as COSV52020934; called by muse, mutect2
- PCLO | c.3972A>G p.P1324= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1471526318; called by muse, varscan2
- PDE4DIP | c.151C>T p.L51= | Silent (SNP) | VAF 21/340 reads (6%) | catalogued as COSV57726791; called by muse, mutect2
- PITPNM2 | c.3852C>T p.G1284= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs764432396; called by muse, mutect2, varscan2
- PLAT | c.1572C>T p.R524= | Silent (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1155C>T p.G385= | Silent (SNP) | VAF 47/266 reads (18%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.600C>T p.P200= | Silent (SNP) | VAF 22/226 reads (10%) | catalogued as rs770653962; called by muse, mutect2
- PROSER2 | c.783C>T p.N261= | Silent (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- PRSS56 | c.615A>G p.G205= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.2967C>T p.D989= | Silent (SNP) | VAF 22/311 reads (7%) | catalogued as rs1163470702; called by muse, mutect2
- RASA4 | c.771G>A p.R257= | Silent (SNP) | VAF 42/438 reads (10%) | called by muse, varscan2
- RBM23 | c.855C>A p.P285= (on ENST00000359890 / NM_001077351.2; = p.P269= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- RP1L1 | c.2742C>T p.S914= | Silent (SNP) | VAF 50/485 reads (10%) | catalogued as rs932203869; called by muse, mutect2, varscan2
- RPTN | c.423C>T p.D141= | Silent (SNP) | VAF 91/547 reads (17%) | catalogued as rs565256584, COSV60167666; called by muse, mutect2, varscan2
- RTEL1 | c.3021C>T p.T1007= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs762149661; called by muse, mutect2, varscan2
- SCARB1 | c.1380C>T p.V460= | Silent (SNP) | VAF 146/547 reads (27%) | called by muse, mutect2, varscan2
- SIMC1 | c.240A>G p.T80= (on ENST00000443967 / NM_001308196.1; = p.T99= on NM_001308195.2) | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as COSV100365316; called by muse, mutect2
- SLC15A5 | c.1443A>G p.T481= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs375574931; called by muse, mutect2
- SLC25A25 | c.456C>T p.P152= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as rs754116133; called by muse, mutect2
- SLC25A38 | c.366C>A p.T122= | Silent (SNP) | VAF 109/317 reads (34%) | called by muse, mutect2, varscan2
- SLC41A1 | c.1245C>T p.L415= | Silent (SNP) | VAF 56/328 reads (17%) | catalogued as rs541250820; called by muse, mutect2, varscan2
- SLC6A18 | c.1272G>A p.A424= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs768735435; called by muse, mutect2, varscan2
- SPRED2 | c.1098G>A p.S366= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as rs141482859; called by muse, mutect2
- SUPT6H | c.4305C>T p.C1435= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as rs1445233446; called by muse, mutect2, varscan2
- TACR3 | c.507G>A p.V169= | Silent (SNP) | VAF 102/330 reads (31%) | catalogued as rs199807810; called by muse, mutect2, varscan2
- TAS2R4 | c.849A>C p.T283= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2
- TBC1D28 | c.36C>A p.A12= | Silent (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- TCEA3 | c.75G>A p.G25= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- TENM2 | c.4587C>T p.N1529= (on ENST00000518659 / NM_001122679.2; = p.N1290= on NM_001080428.3) | Silent (SNP) | VAF 35/144 reads (24%) | called by muse, mutect2, varscan2
- TMEM132E | c.1176A>G p.L392= (on ENST00000321639; = p.L482= on NM_001304438.2) | Silent (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- TMEM176A | c.363A>G p.L121= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- TMEM269 | c.303C>T p.F101= (on ENST00000536543; = p.F59= on NM_001354602.1) | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs532526708, COSV70105708; called by muse, mutect2, varscan2
- TRIM66 | c.3579G>A p.R1193= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV55129478; called by muse, mutect2, varscan2
- TRPM2 | c.4458G>A p.A1486= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs771699014, COSV55974813; called by muse, mutect2, varscan2
- TTC25 | c.585C>T p.Y195= | Silent (SNP) | VAF 53/163 reads (33%) | catalogued as rs372198587; called by muse, mutect2, varscan2
- TTLL7 | c.1014G>A p.L338= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs1381593708; called by muse, mutect2, varscan2
- UMODL1 | c.180C>A p.S60= | Silent (SNP) | VAF 42/296 reads (14%) | called by mutect2, varscan2
- USH2A | c.4416A>G p.P1472= | Silent (SNP) | VAF 54/357 reads (15%) | catalogued as rs1261889108; called by muse, mutect2, varscan2
- VRK1 | c.222C>A p.P74= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV53708098; called by muse, mutect2, varscan2
- ZBTB40 | c.1824T>C p.T608= | Silent (SNP) | VAF 116/385 reads (30%) | called by muse, mutect2, varscan2
- ZFHX3 | c.10950G>A p.G3650= | Silent (SNP) | VAF 64/183 reads (35%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.3747C>A p.L1249= | Silent (SNP) | VAF 80/257 reads (31%) | catalogued as COSV61326040; called by muse, mutect2, varscan2
- ZNRF1 | c.279C>A p.S93= | Silent (SNP) | VAF 47/167 reads (28%) | catalogued as rs750129264; called by muse, mutect2, varscan2
- AACS | c.358+1634T>C | Intron (SNP) | VAF 24/390 reads (6%) | catalogued as rs781013191; called by muse, mutect2
- AC107023.1 | n.25+674G>A | Intron (SNP) | VAF 30/149 reads (20%) | catalogued as rs557019918; called by muse, mutect2, varscan2
- ACSF3 | c.-298C>T | 5'UTR (SNP) | VAF 40/182 reads (22%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2436+22G>A | Intron (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- AKAP1 | c.-25+985_-25+987del | Intron (DEL) | VAF 16/144 reads (11%) | catalogued as rs1281306398; called by mutect2, pindel, varscan2
- AKAP9 | c.9431-31A>G | Intron (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826245 del T | 3'Flank (DEL) | VAF 146/488 reads (30%) | catalogued as rs768711387; called by mutect2, varscan2
- ANKRD11 | c.-59-6238C>T | Intron (SNP) | VAF 54/197 reads (27%) | catalogued as rs1368394157; called by muse, mutect2, varscan2
- ARL10 | chr5:176386815 A>G | 3'Flank (SNP) | VAF 106/369 reads (29%) | catalogued as rs371095698; called by muse, mutect2, varscan2
- BBS1 | c.831-28G>A | Intron (SNP) | VAF 104/332 reads (31%) | called by muse, mutect2, varscan2
- BNIP2 | chr15:59689379 T>C | 5'Flank (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- C11orf58 | c.148-15del | Intron (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- CALU | c.415+118C>T | Intron (SNP) | VAF 40/101 reads (40%) | catalogued as rs377059578; called by muse, mutect2, varscan2
- CCNJL | c.888-563del | Intron (DEL) | VAF 6/27 reads (22%) | catalogued as rs997521306; called by mutect2, pindel, varscan2
- CDH23 | c.3369+477G>T | Intron (SNP) | VAF 34/133 reads (26%) | catalogued as rs764860341; called by muse, varscan2
- CPLX2 | c.*124C>A | 3'UTR (SNP) | VAF 26/118 reads (22%) | called by muse, varscan2
- CRTAC1 | c.1819+463del | Intron (DEL) | VAF 16/182 reads (9%) | called by mutect2, pindel
- CSTF3 | c.27+4567A>T | Intron (SNP) | VAF 55/147 reads (37%) | called by muse, mutect2, varscan2
- D2HGDH | c.1141-351T>C | Intron (SNP) | VAF 22/289 reads (8%) | called by muse, mutect2
- DIS3L2 | chr2:232340882 A>T | 3'Flank (SNP) | VAF 103/375 reads (27%) | called by muse, mutect2, varscan2
- DTNBP1 | c.811+319G>A | Intron (SNP) | VAF 89/276 reads (32%) | called by muse, mutect2, varscan2
- EFHC1 | c.*290del | 3'UTR (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- EGLN1 | c.*9A>C | 3'UTR (SNP) | VAF 68/380 reads (18%) | called by muse, varscan2
- ERAL1 | chr17:28861339 A>G | 3'Flank (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- ESR1 | c.-10G>A | 5'UTR (SNP) | VAF 24/366 reads (7%) | called by muse, mutect2
- EYS | c.7724-14del | Intron (DEL) | VAF 37/142 reads (26%) | catalogued as rs750831969; called by mutect2, pindel, varscan2
- FABP5P3 | chr7:152446270 C>T | 3'Flank (SNP) | VAF 32/372 reads (9%) | called by muse, mutect2
- FAM20A | c.*193G>A | 3'UTR (SNP) | VAF 23/76 reads (30%) | catalogued as rs150972449; called by muse, mutect2, varscan2
- GDAP1 | c.*2055A>T | 3'UTR (SNP) | VAF 30/99 reads (30%) | catalogued as rs780873355; called by muse, mutect2, varscan2
- HEXA | c.805+34C>T | Intron (SNP) | VAF 78/224 reads (35%) | called by muse, mutect2, varscan2
- IGSF9B | c.3984-300G>A | Intron (SNP) | VAF 29/243 reads (12%) | catalogued as rs1052066405; called by muse, mutect2, varscan2
- KLF6 | c.*227C>T | 3'UTR (SNP) | VAF 38/112 reads (34%) | catalogued as rs569733614; called by muse, mutect2, varscan2
- KLHL20 | c.597+39G>T | Intron (SNP) | VAF 56/280 reads (20%) | called by muse, mutect2, varscan2
- MED17 | c.775-19del | Intron (DEL) | VAF 92/310 reads (30%) | called by mutect2, pindel, varscan2
- NLE1 | c.18+22C>T | Intron (SNP) | VAF 35/134 reads (26%) | catalogued as rs992830209; called by muse, mutect2, varscan2
- NREP | c.81+743A>G | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- OR52Z1 | n.435G>T | RNA (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- PALD1 | c.-11G>A | 5'UTR (SNP) | VAF 76/216 reads (35%) | called by muse, mutect2, varscan2
- PHF19 | c.465+90G>A | Intron (SNP) | VAF 84/264 reads (32%) | catalogued as rs900919637; called by muse, mutect2
- PLXNC1 | c.3598-1410del | Intron (DEL) | VAF 52/192 reads (27%) | catalogued as rs777255489; called by mutect2, pindel, varscan2
- PNPLA2 | c.*38T>A | 3'UTR (SNP) | VAF 40/200 reads (20%) | called by muse, mutect2, varscan2
- POU2F1 | c.*294A>G | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- PRPF3 | c.1641-23T>C | Intron (SNP) | VAF 84/484 reads (17%) | called by muse, mutect2, varscan2
- RPL18 | c.492-12_492-10del | Intron (DEL) | VAF 8/45 reads (18%) | called by pindel, varscan2
- SCN4B | c.*2931C>T | 3'UTR (SNP) | VAF 19/159 reads (12%) | catalogued as rs779486807; called by muse, mutect2, varscan2
- SCN4B | c.*2755G>A | 3'UTR (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- SEC1P | n.643G>A | RNA (SNP) | VAF 79/451 reads (18%) | catalogued as rs778217268; called by muse, mutect2, varscan2
- SEPTIN7P9 | n.483+1089A>G | Intron (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- SIRT2 | c.226+1483C>T | Intron (SNP) | VAF 34/129 reads (26%) | catalogued as rs905027153; called by muse, mutect2, varscan2
- SLC19A2 | c.1031-14del | Intron (DEL) | VAF 38/230 reads (17%) | called by mutect2, varscan2
- SLC37A4 | c.984+17T>C | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*901A>G | 3'UTR (SNP) | VAF 15/448 reads (3%) | called by muse, mutect2
- SPECC1 | c.2351+4458C>A | Intron (SNP) | VAF 79/285 reads (28%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2526del | Intron (DEL) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- ST3GAL6 | c.167+198T>C | Intron (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- SYT7 | c.215+9127G>A | Intron (SNP) | VAF 64/220 reads (29%) | catalogued as rs560315280; called by muse, mutect2, varscan2
- SYTL1 | c.748-101del | Intron (DEL) | VAF 80/242 reads (33%) | called by mutect2, pindel, varscan2
- TAFA5 | c.-21del | 5'UTR (DEL) | VAF 12/74 reads (16%) | catalogued as COSV100387150; called by mutect2, pindel
- TAOK2 | chr16:29989688 G>A | 3'Flank (SNP) | VAF 33/433 reads (8%) | catalogued as rs200151456; called by muse, mutect2
- TMCO1 | c.*423del | 3'UTR (DEL) | VAF 68/242 reads (28%) | catalogued as rs35952900; called by mutect2, varscan2
- TMEM129 | c.206-594C>A | Intron (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.-663-737G>T | Intron (SNP) | VAF 49/168 reads (29%) | called by muse, mutect2, varscan2
- TOR1AIP1 | c.475+730del | Intron (DEL) | VAF 10/124 reads (8%) | called by mutect2, pindel
- TRIM74 | chr7:72954833 C>A | 3'Flank (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- TSC2 | c.4989+20T>G | Intron (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- UNC5A | c.722-643G>A | Intron (SNP) | VAF 16/39 reads (41%) | catalogued as rs1014281968, COSV56166653; called by muse, mutect2, varscan2
- XPA | c.*282C>T | 3'UTR (SNP) | VAF 33/142 reads (23%) | called by muse, varscan2
- ZRSR2 | c.203+1574A>G | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
